Gene-level copy-number profile of tumor specimen C3N-03802-01 from CPTAC case C3N-03802, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.7 years (24,015 days).
Specimen C3N-03802-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 87ee342f-aea1-403a-be3e-4df4b038bc97.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03802-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/5e433dcd-6d3b-406d-b7bf-fd7f04837b65

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 8,809; copy number 2: 43,921; copy number 3: 6,059; copy number 4: 4; copy number 5: 9; copy number 7: 23; copy number 8: 5; copy number 10: 35; copy number 11: 6; copy number 20: 16; copy number 23: 18.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–21,967,751, 1 gene (within-gene range 0–1): CDKN2A-DT.
- chr9:39,983,793–40,106,611, 1 gene (within-gene range 0–3): AL772307.1.
- chr9:40,105,822–40,153,147, 4 genes: AL773545.3, CDRT15P14, AL773545.1, AL773545.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 112 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:26,481,396–27,025,381, 6 genes, copy number 7: CCKAR, TBC1D19, AC107390.1, STIM2, STIM2-AS1, PIMREGP4.
- chr4:35,487,812–36,347,511, 6 genes, copy number 5–8 (within-gene range 2–8): SEC63P2, RNU6-573P, ARAP2, AC098827.1, AC104078.1, DTHD1.
- chr4:45,480,030–45,480,136, 1 gene, copy number 8: RNU6-931P.
- chr4:54,229,280–54,740,715, 6 genes, copy number 5 (within-gene range 2–5): PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT.
- chr4:59,833,175–59,834,167, 2 genes, copy number 7: Y_RNA, RNU6-1325P.
- chr4:63,465,511–63,529,761, 1 gene, copy number 5: AC093730.1.
- chr4:64,767,130–65,217,433, 5 genes, copy number 7: AC104689.1, LINC02232, AC107058.1, EFL1P2, AC096754.1.
- chr12:47,782,722–47,833,132, 1 gene, copy number 20 (within-gene range 2–20): HDAC7.
- chr12:47,817,451–48,106,079, 15 genes, copy number 20 (within-gene range 2–20): AC004466.2, LINC02354, VDR, AC121338.1, AC121338.2, AC004801.7, TMEM106C, COL2A1, AC004801.5, AC004801.4, AC004801.3, AC004801.6, SENP1, AC004801.2, RNU6-1203P.
- chr12:52,585,589–52,680,407, 6 genes, copy number 11: KRT72, KRT73-AS1, KRT73, KRT128P, KRT2, KRT1.
- chr12:57,452,323–57,808,071, 35 genes, copy number 10: INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AC025165.5, RNU6-1083P.
- chr12:69,212,108–69,699,476, 18 genes, copy number 23: AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3.
- chr17:11,598,470–12,215,267, 10 genes, copy number 7: DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1, AC005244.2.

Autosomal genes at a single copy (total copy number 1): 5,954. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
